HCMI case HCM-STAN-0840-C49 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/890b4995-c64f-4d1f-bfd3-131e318e8ac3

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1952; Vital status: Dead; Days to death: 318 days.

Diagnoses (1)
1. Giant cell sarcoma: ICD-O-3 morphology code: 8802/3; ICD-10 code: C49.9; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 67.4 years (24,606 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IV; AJCC pathologic T: T4; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage IV; Tumor grade: G4; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: Yes; Sites of involvement: Lung, NOS.
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 0; Lymphatic invasion present: No; Necrosis present: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Brachytherapy, High Dose; Treatment intent type: Neoadjuvant; Days to treatment start: 18 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Ifosfamide; Treatment intent type: Neoadjuvant; Days to treatment start: 18 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel + Gemcitabine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 78 days; Days to treatment end: 304 days.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 78 days.
   Recorded as not given: adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 0 days.
- Days to follow up: 318 days; Disease response: Progressive Disease; Progression or recurrence: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 57.2 kg; Height: 155.9 cm; BMI: 23.5.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-STAN-0840-C49-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-STAN-0840-C49-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 56; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 22; Percent stromal cells: 22; Percent lymphocyte infiltration: 12; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
  Slide HCM-STAN-0840-C49-06A-01-S1-HE: Section location: Top; Percent tumor cells: 30; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 13; Percent stromal cells: 57; Percent lymphocyte infiltration: 12; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample HCM-STAN-0840-C49-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample HCM-STAN-0840-C49-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
